Gene-level copy-number profile of tumor specimen TCGA-04-1369-01A from TCGA case TCGA-04-1369, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 53.6 years (19,571 days).
Specimen TCGA-04-1369-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.2aa36c4f-8057-498b-832c-127ecff9cb03.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-04-1369-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate.
https://portal.gdc.cancer.gov/files/89d6c628-dd1a-4612-923d-e2c1623a15a2

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 1,364; copy number 2: 13,945; copy number 3: 24,002; copy number 4: 12,734; copy number 5: 5,402; copy number 6: 1,435; copy number 7: 381; copy number 8: 431; copy number 9: 45; copy number 10: 28; copy number 11: 2; copy number 12: 15; copy number 14: 26.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:155,491,336–155,493,598, 1 gene: AC008725.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 928 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:150,045,660–151,953,985, 110 genes, copy number 7 (broad region; genes not listed).
- chr2:42,143,238–42,332,548, 2 genes, copy number 7: EML4-AS1, EML4.
- chr2:60,336,446–61,018,259, 22 genes, copy number 7 (within-gene range 6–7): MIR4432HG, AC007381.1, RNU1-32P, MIR4432, BCL11A, AC009970.1, RN7SL361P, IFITM3P9, RPL26P13, RNU6-612P, ATP1B3P1, PAPOLG, LINC01185, RN7SL632P, RPL21P33, REL, RNU4-51P, AC010733.1, NONOP2, RPS12P3, PUS10, RNA5SP95.
- chr2:169,479,480–171,434,802, 38 genes, copy number 7 (within-gene range 3–7): BBS5, AC093899.2, KLHL41, FASTKD1, AC093899.1, PPIG, CCDC173, AC016772.1, PHOSPHO2, KLHL23, AC009967.1, PTCHD3P2, CYB5AP2, SSB, METTL5, UBR3, NSA2P5, RNU6-1006P, MYO3B, MYO3B-AS1, HMGB1P4, AC007277.1, AC007277.2, AC007405.1, LINC01124, SP5, EIF2S2P4, AC007405.3, Y_RNA, ERICH2, GAD1, AC007405.2, AC007405.4, AC010092.1, GORASP2, TLK1, METTL8, RPS26P20.
- chr3:8,931,495–8,931,632, 2 genes, copy number 11: AC034186.2, AC034186.1.
- chr3:182,644,214–198,222,513, 376 genes, copy number 8–12 (broad region; genes not listed).
- chr4:173,094,868–173,169,652, 2 genes, copy number 8: AC105285.1, RN7SL253P.
- chr5:36,861,736–40,067,200, 54 genes, copy number 8: AC026741.1, NIPBL-DT, NIPBL, KRT18P31, RPS4XP6, CPLANE1, RBISP2, OFD1P17, RN7SL37P, AC025449.2, AC025449.1, NUP155, RNU7-75P, AC117532.1, WDR70, KCTD9P5, RNU6-1190P, RNU6-484P, GDNF-AS1, GDNF, LINC02117, AC008869.1, LINC02110, AC034226.1, LINC02119, AC010338.1, EGFLAM, EGFLAM-AS4, EGFLAM-AS3, EGFLAM-AS2, EGFLAM-AS1, AC091839.1, AC010457.1, LIFR, LIFR-AS1, MIR3650, AC010425.1, OSMR-AS1, AC091435.1, AC091435.2, OSMR, RICTOR, AIG1P1, AC008964.1, FYB1, GOLGA5P1, C9, DAB2, LINC02104, CCDC11P1, INTS6P1, GCSHP1, LINC00603, KRT18P56.
- chr7:25,593,304–26,376,701, 13 genes, copy number 8: AC005165.1, AC005165.2, AC005165.3, AC018706.1, AC010719.1, MIR148A, NFE2L3, HNRNPA2B1, CBX3, AC010677.2, AC010677.1, SNX10, AC004540.2.
- chr9:8,700,595–9,091,245, 6 genes, copy number 7: AL583805.2, AL583805.1, RNU7-185P, PTPRD-AS1, AL596451.1, RPS26P3.
- chr9:12,685,439–17,503,923, 63 genes, copy number 7–8 (broad region; genes not listed).
- chr10:81,870,778–81,875,133, 1 gene, copy number 8: AL096706.1.
- chr11:71,833,200–74,669,117, 112 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr12:70,239,114–70,354,993, 3 genes, copy number 8: AC092881.2, CNOT2, AC092881.1.
- chr13:95,019,235–95,579,759, 7 genes, copy number 8 (within-gene range 4–8): RNU6-62P, ABCC4, RNY3P8, RNY4P27, MEMO1P5, CLDN10, CLDN10-AS1.
- chr16:46,556,089–46,851,254, 16 genes, copy number 7–8: RNU6-845P, AC092368.2, AC092368.1, SHCBP1, AC092368.3, RAB43P1, AC012186.1, VPS35, AC012186.2, AC012186.3, ORC6, MYLK3, AC007225.1, C16orf87, CKBP1, AC007225.2.
- chr18:61,592,375–65,448,167, 51 genes, copy number 7–10 (within-gene range 6–10): AC105094.2, AC105094.1, LINC01544, RNF152, PIGN, RPIAP1, RELCH, AC027514.1, AC027514.2, TNFRSF11A, Y_RNA, AC100843.1, RPL17P44, AC100843.2, ACTBP9, ZCCHC2, AC064801.1, AC064801.2, RN7SL705P, PHLPP1, RNU6-142P, BCL2, AC022726.1, AC022726.2, KDSR, AC036176.1, VPS4B, AC036176.2, SERPINB5, AC036176.3, ATP5MC1P6, SERPINB12, SERPINB13, SERPINB4, SERPINB11, SERPINB3, SERPINB7, SERPINB2, SERPINB10, HMSD, AC009802.1, SERPINB8, LINC01924, RPL12P39, LINC00305, LINC01538, AC027506.1, AC090348.1, AC007948.1, AC007631.1, LINC01916.
- chr19:28,316,705–30,713,538, 50 genes, copy number 8–14 (within-gene range 4–14): AC005580.1, AC093074.1, AC005307.1, AC005394.2, AC005381.1, AC005394.1, AC005616.1, AC079466.2, AC079466.1, AC005524.1, MAN1A2P1, AC007795.1, LINC00906, AC008991.1, AC011524.1, AC011524.2, RNA5SP470, LINC01532, AC011505.1, UQCRFS1, AC007786.1, AC007786.2, AC007786.3, RN7SL340P, AC007786.4, AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, AC008798.3, CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC008507.4, AC008507.5, AC005597.1, ZNF536, AC011504.1, AC011478.1.

Autosomal genes at a single copy (total copy number 1): 1,096. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
